Somatic mutation profile of cancer-model specimen HCM-BROD-0229-C25-85A (3D Organoid, passage 9; aliquot HCM-BROD-0229-C25-85A-01D-A786-36), derived from the metastatic tumor of HCMI case HCM-BROD-0229-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; Age at diagnosis: 60.6 years (22,116 days).
Specimen HCM-BROD-0229-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb22758b-5116-4d2b-b093-f899771b2161.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0229-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0229-C25-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7505096f-3f5f-4faf-9ddd-9a8b47195e41

The open-access MAF lists 79 somatic variants for this specimen: 52 protein-altering or splice-affecting, 13 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 45, Silent 13, Intron 9, RNA 3, Frame Shift Ins 2, Splice Site 2, Frame Shift Del 2, Nonsense Mutation 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 100/271 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS1 | c.1810C>T p.R604C | Missense Mutation (SNP) | VAF 66/132 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs770017773, COSV53170046; called by muse, mutect2, varscan2
- ADAMTSL5 | c.505G>T p.G169W | Missense Mutation (SNP) | VAF 102/103 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100389042; called by muse, mutect2, varscan2
- ADGRL4 | c.1486C>A p.L496M | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs867979983; called by muse, mutect2
- APBB1 | c.1114G>A p.V372M | Missense Mutation (SNP) | VAF 81/144 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371824310; called by muse, mutect2, varscan2
- ARHGEF10 | c.1335+1G>T p.X445_splice (on ENST00000398564; = p.X420_splice on NM_014629.4) | Splice Site (SNP) | VAF 95/194 reads (49%) | catalogued as COSV50670705; called by muse, mutect2, varscan2
- ARMCX1 | c.341C>T p.T114M | Missense Mutation (SNP) | VAF 74/151 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.119); catalogued as rs370404366, COSV65705552; called by muse, mutect2, varscan2
- C22orf23 | c.415C>T p.R139W | Missense Mutation (SNP) | VAF 66/153 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); catalogued as rs143633550; called by muse, mutect2, varscan2
- CDKN2A | c.125del p.N42Ifs*11 | Frame Shift Del (DEL) | VAF 82/112 reads (73%) | catalogued as COSV58690205, COSV58691614; called by mutect2, pindel, varscan2
- CENPS-CORT | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.857); catalogued as COSV58364046; called by muse, mutect2
- CLASP1 | c.4232C>T p.A1411V | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as rs779710005; called by muse, mutect2
- CPLX4 | c.475G>A p.V159M | Missense Mutation (SNP) | VAF 56/57 reads (98%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs202101844, COSV55312776; called by muse, mutect2, varscan2
- CWF19L2 | c.2077G>C p.G693R | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV56518717; called by muse, mutect2
- FSIP2 | c.8038dup p.T2680Nfs*9 | Frame Shift Ins (INS) | VAF 44/100 reads (44%) | catalogued as rs755234663; called by mutect2, varscan2
- HSPB2 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 113/138 reads (82%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV57051700; called by muse, mutect2, varscan2
- HUWE1 | c.12245G>A p.R4082H | Missense Mutation (SNP) | VAF 118/249 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs797045618, COSV53338682; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCND3 | c.1370C>T p.T457M | Missense Mutation (SNP) | VAF 207/440 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs199637120, COSV56182786; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KPNA1 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1398957671; called by muse, varscan2
- LCT | c.4833G>T p.Q1611H | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV99930288; called by muse, mutect2
- MAOB | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 46/80 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65204929; called by muse, mutect2, varscan2
- OR8G2P | c.353C>T p.T118M | Missense Mutation (SNP) | VAF 106/146 reads (73%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs566362808; called by muse, varscan2
- PTPN5 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 81/153 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.525); catalogued as rs144630372; called by muse, mutect2, varscan2
- RCAN2 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as COSV60769969; called by muse, mutect2
- RTL1 | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 56/129 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as rs1008960435, COSV66017663; called by muse, mutect2, varscan2
- SAFB2 | c.1262C>T p.T421M | Missense Mutation (SNP) | VAF 72/72 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as rs1395075913, COSV99385419; called by muse, mutect2, varscan2
- SALL1 | c.2792C>T p.P931L | Missense Mutation (SNP) | VAF 250/405 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs140924793, COSV51764357; called by muse, mutect2, varscan2
- SOX11 | c.431G>C p.G144A | Missense Mutation (SNP) | VAF 124/283 reads (44%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs1475737480; called by mutect2, varscan2
- TAF7 | c.166G>A p.V56I | Missense Mutation (SNP) | VAF 175/351 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); catalogued as COSV57665682; called by muse, mutect2, varscan2
- TNPO3 | c.1417G>A p.V473I | Missense Mutation (SNP) | VAF 115/244 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as rs150330408; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TREM2 | c.65C>A p.T22K | Missense Mutation (SNP) | VAF 36/248 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs760511786; called by muse, mutect2, varscan2
- AIMP2 | c.89T>A p.V30E | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- ARHGAP9 | c.2095T>A p.S699T (on ENST00000393797 / NM_001319850.2; = p.S680T on NM_032496.4) | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2
- ATP11C | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ATP13A3 | c.1145G>C p.R382T | Missense Mutation (SNP) | VAF 129/289 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- DCLK2 | c.332C>A p.S111* | Nonsense Mutation (SNP) | VAF 64/139 reads (46%) | called by muse, mutect2, varscan2
- DEPDC5 | c.3339G>C p.W1113C (on ENST00000400246; = p.W1182C on NM_014662.5) | Missense Mutation (SNP) | VAF 99/220 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DST | c.10026A>C p.E3342D | Missense Mutation (SNP) | VAF 8/201 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.461); called by muse, mutect2
- H1-2 | c.530C>G p.A177G | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.084); called by muse, mutect2
- HYDIN | c.11772C>G p.F3924L | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IFT57 | c.785G>A p.R262K | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KBTBD6 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 118/257 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- L3MBTL4 | c.344_350del p.R115Ifs*6 | Frame Shift Del (DEL) | VAF 23/57 reads (40%) | called by mutect2, pindel, varscan2
- LRRC30 | c.758T>G p.L253R | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.543); called by muse, mutect2
- MFN2 | c.65C>G p.A22G | Missense Mutation (SNP) | VAF 124/287 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.7); called by muse, mutect2, varscan2
- NOL12 | c.479+2T>C p.X160_splice | Splice Site (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- OR7G3 | c.442T>A p.S148T | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- RNASEH2B | c.13G>C p.V5L | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.007); called by muse, mutect2
- SLC35A5 | c.604A>C p.K202Q | Missense Mutation (SNP) | VAF 125/256 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- SMAD4 | c.1586dup p.L529Ffs*48 | Frame Shift Ins (INS) | VAF 82/117 reads (70%) | called by mutect2, pindel, varscan2
- SSTR1 | c.894G>C p.E298D | Missense Mutation (SNP) | VAF 33/245 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TRIM8 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 349/349 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF98 | c.95C>A p.T32N | Missense Mutation (SNP) | VAF 66/191 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ACBD4 | c.507C>T p.S169= | Silent (SNP) | VAF 12/230 reads (5%) | catalogued as COSV58853577; called by muse, mutect2
- CARD11 | c.1704G>A p.P568= | Silent (SNP) | VAF 14/203 reads (7%) | catalogued as rs539901942; called by muse, mutect2
- CELF2 | c.867T>A p.A289= (on ENST00000416382 / NM_001025077.3; = p.A296= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 103/230 reads (45%) | called by muse, mutect2, varscan2
- CILP2 | c.1542G>A p.P514= | Silent (SNP) | VAF 84/215 reads (39%) | catalogued as rs749762474; called by muse, mutect2, varscan2
- DDX21 | c.1755C>T p.S585= | Silent (SNP) | VAF 44/82 reads (54%) | catalogued as rs1252350646; called by muse, mutect2, varscan2
- HMOX2 | c.837C>T p.G279= | Silent (SNP) | VAF 50/107 reads (47%) | called by muse, mutect2, varscan2
- PCDHGA2 | c.2232C>T p.D744= | Silent (SNP) | VAF 240/585 reads (41%) | catalogued as COSV53897900; called by muse, mutect2, varscan2
- PEG3 | c.4257C>T p.N1419= | Silent (SNP) | VAF 88/210 reads (42%) | catalogued as rs1187440479; called by muse, mutect2, varscan2
- SYNE1 | c.24883C>T p.L8295= (on ENST00000367255 / NM_182961.4; = p.L8224= on NM_033071.3) | Silent (SNP) | VAF 72/142 reads (51%) | called by muse, mutect2, varscan2
- TBX20 | c.225G>A p.P75= | Silent (SNP) | VAF 112/212 reads (53%) | catalogued as rs369044150; ClinVar: likely benign; called by muse, mutect2, varscan2
- TMEM259 | c.597G>A p.T199= | Silent (SNP) | VAF 62/118 reads (53%) | catalogued as rs767816573; called by muse, mutect2, varscan2
- ZDHHC24 | c.444C>T p.G148= | Silent (SNP) | VAF 231/445 reads (52%) | catalogued as rs751956084, COSV60080293; called by muse, mutect2, varscan2
- ZNF184 | c.1326G>A p.G442= | Silent (SNP) | VAF 67/113 reads (59%) | called by muse, mutect2, varscan2
- AC008060.1 | n.253G>T | RNA (SNP) | VAF 10/278 reads (4%) | called by muse, mutect2
- BEST1 | c.*9C>A | 3'UTR (SNP) | VAF 34/318 reads (11%) | called by muse, mutect2
- CASZ1 | c.2816+37A>G | Intron (SNP) | VAF 86/257 reads (33%) | called by muse, mutect2, varscan2
- CCNYL2 | n.991C>T | RNA (SNP) | VAF 58/128 reads (45%) | catalogued as rs1355645756; called by muse, mutect2, varscan2
- EGF | c.2222-22A>T | Intron (SNP) | VAF 127/277 reads (46%) | called by muse, mutect2, varscan2
- HNRNPA1 | c.-34A>G | 5'UTR (SNP) | VAF 16/267 reads (6%) | called by muse, mutect2
- LINC00905 | n.594G>A | RNA (SNP) | VAF 112/188 reads (60%) | called by muse, mutect2, varscan2
- MRPL3 | c.630-7892A>G | Intron (SNP) | VAF 27/205 reads (13%) | called by muse, mutect2, varscan2
- NRIP1 | c.-537-7331T>G | Intron (SNP) | VAF 97/198 reads (49%) | called by muse, mutect2, varscan2
- NSMAF | c.150-1803G>T | Intron (SNP) | VAF 60/142 reads (42%) | catalogued as rs1328941882; called by muse, mutect2, varscan2
- NTN5 | c.1105+201T>A | Intron (SNP) | VAF 16/116 reads (14%) | called by muse, mutect2, varscan2
- PHACTR1 | c.664+2131C>A | Intron (SNP) | VAF 112/207 reads (54%) | called by muse, mutect2, varscan2
- PLEKHG3 | c.352-345C>T | Intron (SNP) | VAF 8/182 reads (4%) | called by muse, mutect2
- ST6GAL1 | c.706-20T>G | Intron (SNP) | VAF 62/196 reads (32%) | called by muse, mutect2, varscan2
